Somatic mutation profile of tumor specimen TCGA-ET-A3BQ-01B (aliquot TCGA-ET-A3BQ-01B-11D-A202-08) from TCGA case TCGA-ET-A3BQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 27.5 years (10,034 days).
Specimen TCGA-ET-A3BQ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ed11f5e-d2d9-47a9-9475-21dcb3bbb262.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BQ-10A (Blood Derived Normal), aliquot TCGA-ET-A3BQ-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17b4075e-a2fd-4905-b55a-eb161dd2bdb2

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARHGEF40 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs371889536, COSV53882688; called by muse, mutect2, varscan2
- ASB10 | c.772G>A p.V258I (on ENST00000420175 / NM_001142459.2; = p.V243I on NM_080871.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs746844082, COSV51999007; called by muse, mutect2, varscan2
- B3GNTL1 | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57951952; called by muse, mutect2
- CCDC39 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV56490026; called by muse, mutect2, varscan2
- SVIL | c.5335G>T p.D1779Y (on ENST00000355867 / NM_021738.3; = p.D1353Y on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63446312; called by muse, mutect2, varscan2
- UBE2F | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.494); catalogued as COSV56027036; called by muse, mutect2, varscan2
- WIPF1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55818421; called by muse, mutect2, varscan2
- INPP5F | c.2902_2903del p.Q968Efs*17 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by pindel, varscan2
- VAV3 | c.1374C>T p.T458= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs143070546, COSV58384676, COSV58388682; ClinVar: likely benign; called by muse, mutect2, varscan2
